Somatic mutation profile of tumor specimen MMRF_2289_1_BM_CD138pos (aliquot MMRF_2289_1_BM_CD138pos_T1_KHS5U_L09531) from MMRF case MMRF_2289, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.7 years (19,246 days).
Specimen MMRF_2289_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6df4a1c3-54c2-496f-92a3-fea020a9187f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2289_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2289_1_PB_Whole_C3_KHS5U_L09532; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1842a7b-f584-4d4c-88fd-fbea9181db48

The open-access MAF lists 88 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 21, Silent 14, Intron 9, Splice Site 3, Splice Region 3, 5'UTR 2, 5'Flank 2, RNA 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASS | c.1875G>A p.T625= | Splice Region (SNP) | VAF 50/97 reads (52%) | catalogued as rs201088331; called by muse, mutect2, varscan2
- C15orf39 | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs200600379; called by muse, mutect2, varscan2
- C15orf40 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.237); catalogued as rs565635076, COSV55603757; called by muse, mutect2, varscan2
- C6orf89 | c.727C>T p.R243C (on ENST00000373685; = p.R250C on NM_152734.4) | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs143348146; called by muse, mutect2, varscan2
- CD74 | c.726G>C p.Q242H | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50532246; called by muse, mutect2, varscan2
- CDK20 | c.501-4G>A | Splice Region (SNP) | VAF 28/102 reads (27%) | catalogued as rs774893751; called by muse, mutect2, varscan2
- CYP27C1 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1293725930, COSV100079987; called by muse, mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | catalogued as rs747773579; called by mutect2, varscan2
- GUCY1A2 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777255899, COSV56497674; called by muse, mutect2, varscan2
- IGHJ1 | c.7T>G p.Y3D | Missense Mutation (SNP) | VAF 14/16 reads (88%) | catalogued as rs527445203; called by muse, varscan2
- IGHV2-70 | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs374765470; called by mutect2, varscan2
- IGHV3-23 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.263); catalogued as rs1343555427; called by muse, mutect2, varscan2
- IGHV3-23 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as rs781828337; called by muse, varscan2
- IGLV3-1 | c.47-2A>G p.X16_splice | Splice Site (SNP) | VAF 33/77 reads (43%) | catalogued as rs181922188; called by muse, varscan2
- IGLV3-1 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs750748369; called by muse, varscan2
- IGLV3-1 | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs774205851; called by muse, varscan2
- LRP5 | c.3955G>A p.G1319S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs968164869, COSV99591748; called by muse, mutect2, varscan2
- PCDHA10 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV56539434; called by muse, mutect2, varscan2
- TBC1D16 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); catalogued as rs373599883; called by muse, mutect2, varscan2
- ZNF730 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 62/94 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1319053829; called by muse, mutect2, varscan2
- CBFB | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FADS2 | c.1136T>G p.L379R | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBXO47 | c.848A>T p.K283I | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- GUCY2C | c.751G>C p.G251R | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV1-69D | c.312C>G p.S104R | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by muse, varscan2
- IGKV1-8 | c.174A>C p.Q58H | Missense Mutation (SNP) | VAF 75/84 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- ITGAV | c.2821A>C p.K941Q | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.198); called by muse, varscan2
- LRRC4C | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- METTL21A | c.259+1G>A p.X87_splice | Splice Site (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- PPP1R3C | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RYR2 | c.14591-2A>C p.X4864_splice | Splice Site (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- SERPINB13 | c.340T>C p.Y114H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by mutect2, varscan2
- SRRM1 | c.2275C>A p.P759T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSMEM1 | c.473A>C p.E158A | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- STING1 | c.228-5C>G | Splice Region (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- TOR3A | c.133T>C p.F45L | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTBK2 | c.1613T>C p.V538A | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ARGLU1 | c.801C>T p.F267= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs369814396; called by muse, mutect2, varscan2
- CACNA1H | c.6621C>T p.S2207= | Silent (SNP) | VAF 61/106 reads (58%) | catalogued as rs371375487; called by muse, mutect2, varscan2
- CATSPERB | c.690T>G p.T230= | Silent (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
- IGHV1-24 | c.336G>A p.V112= | Silent (SNP) | VAF 53/100 reads (53%) | catalogued as rs543763598; called by muse, mutect2, varscan2
- IGLL5 | c.81G>A p.L27= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs56055217, COSV73249379; called by muse, mutect2, varscan2
- IGLV3-1 | c.72T>G p.T24= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs191429645; called by muse, varscan2
- IGLV4-69 | c.24C>T p.F8= | Silent (SNP) | VAF 67/162 reads (41%) | called by muse, mutect2, varscan2
- MRPL30 | c.30A>G p.Q10= | Silent (SNP) | VAF 17/196 reads (9%) | catalogued as rs370096693; called by muse, mutect2
- MYH13 | c.1524C>T p.I508= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs760585886; called by muse, mutect2, varscan2
- NLGN4Y | c.1803C>T p.N601= | Silent (SNP) | VAF 67/72 reads (93%) | catalogued as rs1488646696; called by muse, mutect2, varscan2
- PARVB | c.681C>T p.T227= | Silent (SNP) | VAF 18/40 reads (45%) | called by muse, mutect2, varscan2
- RASEF | c.1245G>C p.L415= | Silent (SNP) | VAF 32/130 reads (25%) | called by muse, varscan2
- TNKS | c.621A>T p.V207= | Silent (SNP) | VAF 79/169 reads (47%) | catalogued as rs373769442; called by muse, mutect2, varscan2
- TYW1 | c.2155A>C p.R719= | Silent (SNP) | VAF 62/156 reads (40%) | called by muse, mutect2, varscan2
- AC067904.2 | n.325A>C | RNA (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- AP1B1 | c.2776-135C>T | Intron (SNP) | VAF 5/10 reads (50%) | catalogued as rs554548378, COSV100434908; called by muse, varscan2
- ARL5B | c.*202G>A | 3'UTR (SNP) | VAF 18/48 reads (38%) | catalogued as rs1564867815; called by muse, mutect2, varscan2
- ARPP19 | c.45+21C>T | Intron (SNP) | VAF 22/88 reads (25%) | catalogued as rs761326485; called by muse, mutect2
- ATM | c.*2415A>C | 3'UTR (SNP) | VAF 25/41 reads (61%) | called by muse, mutect2, varscan2
- CACNA1E | c.*6244A>G | 3'UTR (SNP) | VAF 54/71 reads (76%) | called by muse, mutect2, varscan2
- CADM2 | chr3:84959049 C>A | 5'Flank (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- CRIPT | c.*63A>G | 3'UTR (SNP) | VAF 41/69 reads (59%) | catalogued as rs1182135490; called by muse, mutect2, varscan2
- EDN1 | c.*1090A>G | 3'UTR (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.-69G>A | 5'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- EIF5 | c.*2300C>T | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- EPN1 | c.*30C>T | 3'UTR (SNP) | VAF 14/44 reads (32%) | catalogued as rs774393713; called by mutect2, varscan2
- ETNPPL | c.*346G>A | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- FRYL | c.*1815T>G | 3'UTR (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- GABRG2 | c.1249-1427del | Intron (DEL) | VAF 30/51 reads (59%) | catalogued as rs912927082; called by mutect2, varscan2
- HOXC11 | c.*1571G>T | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- LRRC74A | c.217+725C>T | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as rs1012605241; called by muse, mutect2
- LTB | c.162+159G>C | Intron (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- MIR5195 | n.46G>A | RNA (SNP) | VAF 30/66 reads (45%) | catalogued as rs751658774; called by muse, varscan2
- NDUFA5 | c.*2730G>A | 3'UTR (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.*904T>G | 3'UTR (SNP) | VAF 18/67 reads (27%) | called by muse, varscan2
- PARD6B | c.*2829T>C | 3'UTR (SNP) | VAF 32/59 reads (54%) | called by muse, mutect2, varscan2
- RAB2A | c.*890A>G | 3'UTR (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- RBM19 | c.*1115G>A | 3'UTR (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- RIC8A | c.1065+43G>A | Intron (SNP) | VAF 32/85 reads (38%) | catalogued as rs754013316; called by muse, mutect2, varscan2
- RPTN | c.*851G>A | 3'UTR (SNP) | VAF 31/51 reads (61%) | catalogued as rs999356771; called by muse, mutect2, varscan2
- RSBN1 | c.*2026A>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | catalogued as rs943627236, COSV99792880; called by mutect2, varscan2
- S1PR2 | c.-43+722C>T | Intron (SNP) | VAF 59/93 reads (63%) | catalogued as rs571967599, COSV73912781; called by muse, mutect2, varscan2
- SIK1B | c.*573_*594del | 3'UTR (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel
- SLC30A9 | chr4:41990513 C>T | 5'Flank (SNP) | VAF 30/58 reads (52%) | catalogued as rs1474092528; called by muse, mutect2, varscan2
- SYN3 | c.*1015C>T | 3'UTR (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- TAS2R14 | c.*301A>G | 3'UTR (SNP) | VAF 21/48 reads (44%) | catalogued as rs925685361; called by muse, mutect2, varscan2
- TMSB4X | c.-16-211A>C | Intron (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- TTN | c.34523-316_34523-301del | Intron (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- USP53 | c.*1402_*1412delinsCCGG | 3'UTR (DEL) | VAF 14/26 reads (54%) | called by pindel, varscan2*
- ZFP36L1 | c.-1643T>G | 5'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
